Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVV-01A (Primary Tumor).

DIAGNOSIS:

Liver, right, posterior sectionectomy:

Hepatocellular carcinoma, S6

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 4x2.8x2.2cm
- 3) Gross type: multinodular confluent type
- 4) Satellite nodule: present
- 5) Histologic type: trabecular
- 6) Cell type: classic cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 4
The major differentiation: 3
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: present (2%)
- 10) Tumor necrosis: present (5%)
- 11) Vascular invasion(microscopic): present
- 12) Capsule formation: absent
- 13) Septal formation: present
- 14) Involvement of a major branch of the portal vein: absent
- 15) Involvement of a major branch of the hepatic vein: absent
- 16) Bile duct invasion: present
- 17) Serosal invasion: present (Glisson's capsule) (Fibrous adhesion)
- 18) Surgical margin: clear (safety margin: 3cm)
- 19) Intrahepatic metastasis: present
- 20) Multicentric occurrence: absent
- 21) Pathologic stage: AJCC (pT2), (pT4)
- 22) Related biopsy: none
- 23) Additional pathologic findings
- a) Chronic hepatitis, HBV-associated
with minimal lobular activity
mild porto-periportal activity
periportal fibrosis
- b) Cirrhosis: absent
- c) Dysplasia: absent
- d) Bile duct adenoma, 0.15mm in size

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
Q2 4/22/14

Source: NCI Genomic Data Commons file 98d258cc-e7d6-48b6-a287-2de75e53d7ea (TCGA-DD-AAVV.5F24D049-6BE5-403B-9E5A-399921814C68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).